TCGA case TCGA-BB-4227 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Hypopharynx; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b8ac8500-abcd-40c4-9c24-7af557fd260a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C13.9; Tissue or organ of origin: Hypopharynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 66.6 years (24,322 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N2b; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N2b; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 134 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 25; Margin status: Uninvolved.
   Pathology details: Lymph node dissection site: Neck, NOS.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Palliative; Number of cycles: 4.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Palliative; Number of cycles: 4.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Cure; Days to treatment end: 7 days; Treatment outcome: Persistent Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Hypopharynx, NOS. Age at diagnosis: 66.8 years (24,407 days); Days to diagnosis: 85 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 85 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Hypopharynx, NOS; Days to recurrence: 85 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 133 days; Disease response: With Tumor.
- Days to follow up: 134 days; Disease response: With Tumor.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 3; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 25; Tobacco smoking quit year: 1990.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BB-4227-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-BB-4227-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 1; Percent neutrophil infiltration: 10.
  Slide TCGA-BB-4227-01A-01-TS1: Section location: Top; Percent tumor cells: 86; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 4; Percent lymphocyte infiltration: 1; Percent neutrophil infiltration: 10.
- Sample TCGA-BB-4227-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BB-4227-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Tobacco smoking history indicator: 3; Alcohol consumption frequency: 7.
- Drug treatment 1: Regimen number: 1.
- Follow-up form 1: Tumor status: With tumor; Treatment outcome first course: Stable Disease; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 2: Lost to follow-up: Yes; Treatment outcome first course: Progressive Disease; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Days to completion of curative treatment: 7; Definitive treatment method: Surgery; Definitive treatment evidence disease after: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 134 days; disease-specific survival: no event (censored), 134 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 85 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BB-4227-01A-01D-1869-01): tumor purity 0.79, ploidy 1.94, whole-genome doublings 0.
